Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JT, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JT-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAT TYPE:

PAGE #: 1
SEX: F
ADM DATE:

OPER DATE:

PROCEDURE: SPHS

Operative Procedure/Tissue Submitted: Open adrenalectomy-left.

PROCEDURE: SPGD

1. "Left adrenal mass and spleen." Received in formalin in a large container is a 480 gm adrenal mass (11.5 x 10.0 x 8.5 cm) with attached capsular adipose tissue and spleen (160 gm; 11.8 x 7.5 x 2.0 cm). The mass is opened to reveal a tan-yellow, partially necrotic tumor (necrosis) predominantly in the inferior portion with a thickened capsule superiorly and numerous nodules that appear to traverse the capsule into adjacent fat. Inking as follows: superior blue, inferior green, posterior black, anterior yellow, medial red and lateral orange. Eight possible lymph nodes are identified (the largest 1.3 cm) in the periadrenal fat. The splenic vein is opened and appears to be free of tumor. Sectioning of the mass reveals encroachment of the tumor onto periadrenal adipose at multiple margins.

1A-H. Representative sections through capsule.

1I. Largest lymph node trisected

1J. Seven possible lymph nodes.

1K-Q. Representative sections through capsule.

1R. Representative section through spleen at hilum.

2. "Retroperitoneal lymph node dissection." Received in formalin in a small tall container are three fragments of fibroadipose tissue (in aggregate 4.2 x 2.5 x 2.0 cm). Eleven possible lymph nodes identified (0.5 to 1.8 cm).

2A. Seven possible lymph nodes.

2B. Largest possible lymph node bisected.

2C. Next largest lymph node bisected.

2D. One possible lymph node bisected.

2E. One possible lymph node bisected.

Fat retained.

3. "Diaphragm." Received in formalin in a small tall container are two, tan-gray, soft tissue fragments. Submitted whole in 1 cassette.

3A.

ICD-6-3

PROCEDURE: SPMI

ADRENOCORTICAL CARCINOMA
V4

Tumor Size: 11.5 x 10.0 x 8.5 cm

Tumor Weight: 480 grams

Carcinoma, adrenal cortical
8370/3

Site: (C) Adrenal Gland, cortex
C74.0

gnd 1/30/13

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: _____

PAGE #: 2

BIRTHDATE: _____

SEX: F

OPER DATE: _____

Capsular Invasion: No

Vascular Invasion: No

Surgical Margins: Free

Necrosis: Extensive

Mitotic Rate: 5 mitoses per 50 high power field

Grade: Low grade

Lymph nodes status: 0/17 lymph nodes

Extra-adrenal extension: Negative

Stage: T2 N0

PROCEDURE: SPDX

1. Left adrenal gland and spleen, resection: Low grade adrenocortical carcinoma (11.5 cm, 480 gm) with extensive necrosis. No capsular or vascular invasion. Surgical margins free. Nine lymph nodes, negative for carcinoma (0/9). Incidental adrenocortical adenoma. Histologically unremarkable spleen.

2. Soft tissue of retroperitoneum, lymph node dissection: Eight lymph nodes, negative for carcinoma (0/8). Histologically unremarkable ganglia.

3. Diaphragm, resection: Histologically unremarkable fibromuscular tissue. Negative for carcinoma.

_____, signing staff pathologist, have personally examined and interpreted the slides from this case.

Source: NCI Genomic Data Commons file 19031e74-1099-49e1-9a71-e27efd973092 (TCGA-OR-A5JT.095AE671-9808-4895-B6FD-EDA3F7F9E69D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).